Somatic mutation profile of tumor specimen MP2PRT-PARSUS-TMP1-A (aliquot MP2PRT-PARSUS-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PARSUS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,400 days).
Specimen MP2PRT-PARSUS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb8a10a2-927f-4bce-9840-3d1a06352b5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARSUS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARSUS-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8936dd35-1379-494a-b3ca-49711540ac41

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Nonsense Mutation 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 115/248 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADH7 | c.935T>C p.M312T | Missense Mutation (SNP) | VAF 112/437 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1302602015; called by muse, mutect2, varscan2
- C1QL2 | c.57del p.A20Pfs*6 | Frame Shift Del (DEL) | VAF 258/622 reads (41%) | catalogued as COSV55605873; called by mutect2, pindel, varscan2
- PCDH1 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 170/401 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs777936720; called by muse, mutect2, varscan2
- RAB40A | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 262/562 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs778254688; called by muse, mutect2, varscan2
- SEC16B | c.874C>T p.H292Y | Missense Mutation (SNP) | VAF 52/428 reads (12%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs768172323; called by muse, mutect2, varscan2
- TMCC2 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 219/787 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.028); catalogued as rs1445166472, COSV58004733; called by muse, mutect2, varscan2
- TRAV13-1 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 59/592 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs999954913; called by muse, mutect2, varscan2
- TUSC1 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 126/278 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1386483166; called by muse, varscan2
- MUC5B | c.166G>C p.V56L | Missense Mutation (SNP) | VAF 226/504 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SPAST | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 84/201 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- THRAP3 | c.332G>A p.W111* | Nonsense Mutation (SNP) | VAF 184/410 reads (45%) | called by muse, mutect2, varscan2
- CYFIP1 | c.1398C>T p.G466= | Silent (SNP) | VAF 31/665 reads (5%) | called by muse, mutect2
- FEZF1 | c.1029G>A p.P343= | Silent (SNP) | VAF 122/312 reads (39%) | catalogued as rs1432400355, COSV58658143; called by muse, mutect2, varscan2
- HPS3 | c.1296C>T p.F432= | Silent (SNP) | VAF 102/265 reads (38%) | called by muse, varscan2
- ISM1 | c.99C>T p.P33= | Silent (SNP) | VAF 224/500 reads (45%) | catalogued as rs1394234119; called by muse, varscan2
- PRORY | n.524C>T | RNA (SNP) | VAF 103/108 reads (95%) | called by muse, varscan2
